Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NQ-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular
817613

Site: Liver C22.0

9/12/24/12

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 B12 B13 B14 B15

Tissue from liver segment 2/3 (12.0 x 10.0 x 7.0 cm) and tissue from
falciform (1.5 x 0.7 x 0.2 cm).

DIAGNOSIS:

Liver, segment 2/3, resection: Hepatocellular carcinoma, grade 3 (of
4) forming a partially necrotic 7.2 x 6.0 x 6.0 cm mass. Vascular
invasion is identified at the periphery of the tumor. Margins of
resection are negative (minimal tumor free margin 1.8 cm)

Soft tissue, falciform, excision: Negative for malignancy,
fibrovascular and adipose tissue with focal fat necrosis.

Photographed.

HI/PAI Discrepancy		☒
Primary Malignancy History		☒
Dual/Sync Chronic Primary Nod		☒

Source: NCI Genomic Data Commons file 6317d88d-5afe-46b3-93d1-94e84cfb878e (TCGA-DD-A4NQ.D79DB738-2DA3-43F6-898C-4A212964FA03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).